Somatic mutation profile of tumor specimen MP2PRT-PAUTXE-TMP1-A (aliquot MP2PRT-PAUTXE-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAUTXE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,019 days).
Specimen MP2PRT-PAUTXE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b530f31-75bf-40ad-add3-963bd037406d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUTXE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUTXE-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba2319c8-e60f-41ee-9620-6f11fd13f770

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Frame Shift Ins 2, Frame Shift Del 1, Silent 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SH3BP4 | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 78/305 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239838499, COSV60642340; called by muse, mutect2, varscan2
- DCAF4L2 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 95/494 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OPTN | c.1355_1356del p.A452Efs*22 | Frame Shift Del (DEL) | VAF 46/624 reads (7%) | called by mutect2, pindel*
- RUFY3 | c.953_954dup p.E319Rfs*25 | Frame Shift Ins (INS) | VAF 25/251 reads (10%) | called by mutect2, pindel
- SCAF11 | c.1842_1843delinsCCTGAA p.E615Lfs*4 | Frame Shift Ins (INS) | VAF 63/314 reads (20%) | called by pindel, varscan2*
- SZT2 | c.2966T>C p.I989T | Missense Mutation (SNP) | VAF 156/306 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF469 | c.5516C>T p.A1839V (on ENST00000437464; = p.A1867V on NM_001367624.2) | Missense Mutation (SNP) | VAF 98/432 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CALML4 | c.222C>T p.T74= | Silent (SNP) | VAF 70/430 reads (16%) | catalogued as rs1348785944; called by muse, mutect2, varscan2
- NHSL2 | chrX:72143435 T>C | 3'Flank (SNP) | VAF 128/447 reads (29%) | called by muse, mutect2, varscan2
